HCMI case HCM-CSHL-0074-C25 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e3b32485-b204-43a7-93a5-601408fcdf96

Demographics
Sex at birth: male; Year of birth: 1963; Vital status: Alive.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.0; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Head of pancreas; Classification of tumor: primary; Age at diagnosis: 54.2 years (19,813 days); AJCC staging edition: 8th; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: G2; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No.
   Pathology details: Peripancreatic lymph nodes positive: 4 or More; Peripancreatic lymph nodes tested: 40.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -7 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 48 days; Days to treatment end: 218 days.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 229 days; Days to treatment end: 255 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (2 entries)
- Days to follow up: 802 days (2.2 years); Disease response: Complete Response; Progression or recurrence: No.
- Follow-up contact recording only the day: day 245.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 82 kg; Height: 169 cm; BMI: 25.
- Timepoint category: Prior to Diagnosis; Comorbidities: Diabetes, NOS; Days to comorbidity: -5,713 days (-15.6 years); Diabetes treatment type: Injected Insulin.
- Timepoint category: Prior to Diagnosis; Comorbidities: Diabetes, NOS; Days to comorbidity: -5,713 days (-15.6 years); Diabetes treatment type: Biguanide.

Exposures
- Tobacco smoking status: Current Smoker; Alcohol intensity: Non-Drinker.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0074-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0074-C25-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 25; Percent tumor nuclei: 30; Percent normal cells: 10; Percent necrosis: 5; Percent stromal cells: 60; Percent lymphocyte infiltration: 6; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 2.
  Slide HCM-CSHL-0074-C25-01A-01-S1-HE: Section location: Top; Percent tumor cells: 20; Percent tumor nuclei: 20; Percent normal cells: 40; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 25; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 2.
- Sample HCM-CSHL-0074-C25-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-CSHL-0074-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
